Surgical pathology report (de-identified scan), TCGA case TCGA-97-7552, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-7552-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

1. F/S LUNG, LEFT LOWER LOBE
2. STATION 12 LYMPH NODE
3. STATION 11 LYMPH NODE
4. STATION 7 LYMPH NODE
- SEE ADDENDUM

For Addendum #1: Immunohistochemistry Analysis

1. LUNG, LEFT, LOWER LOBE: LOBECTOMY
- MIXED INVASIVE ADENOCARCINOMA AND MUCINOUS TYPE BRONCHIOLOALVEOLAR ADENOCARCINOMA (SEE SUMMARY).
- POST-OBSTRUCTIVE PNEUMONIA.
2. LYMPH NODE, STATION #12: BIOPSY
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
3. LYMPH NODE, STATION #11: BIOPSY
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
4. LYMPH NODE, STATION #7: BIOPSY
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

SUMMARY:

Tumor Size: 5.2 cm
Histologic Type: Invasive adenocarcinoma, acinar/papillary/micropapillary (20%); mucinous type bronchioloalveolar (80%).
Histologic Grade: Well to moderately differentiated (G1-G2).
Margins: Uninvolved by carcinoma.
Direct Extension of Tumor: No visceral pleura invasion identified.
Lymphatic Invasion: Not identified.
Large Vessel Invasion: Not identified.
Pathologic Staging: pT2 N0 Mx.

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

Lung mass left

MACROSCOPIC DESCRIPTION:

The specimen is received fresh in four parts each labeled with the patient's name.

[page 2 of 3]
1. Part one is received fresh for froze section, labeled 'left lower lobe.' It consists of a lobe of lung, measuring 16 x 11.5 x 3.5 cm. On the pleural surface there is a linear defect, measuring 3 x 1 cm. The surface of the lung shows pleural thickening covering an area, which measures 3 cm. Upon opening the lung there is a tan glistening mass, measuring 5.2 x 3.5 x 2.2 cm. It extends up to the pleura. The mass is located 2 cm away from the surgical margin. The mass does not appear to involve the vascular or bronchial margin. No evident lymph nodes are identified within the lung tissue. The specimen is photographed and representative sections are submitted.

2. Part two is labeled 'station #12.' It consists of one gray black lymph node measuring 0.6 x 0.3 x 0.3 cm .It is submitted entirely.

3. Part three is labeled 'station #11.' It consists of a gray black lymph node; measuring 0.9 x 0.5 x 0.4 cm .It is submitted entirely.

4. Part four is labeled 'station #7.' It consists of a gray black lymph node, measuring 1 x 0.6 x 0.4 cm .The cut surface is grossly unremarkable. It is submitted entirely.

[REDACTED]

SUMMARY OF SECTIONS:

1A frozen section control
1B vascular and bronchial margins
1C-H representative section of tumor
1I normal lung with surgical margin
1J-K normal lung
2A submitted entirely
3A submitted entirely
4A entirely submitted

INTRA - OPERATIVE CONSULTATION:

1. Lung, left lower lobe: Lobectomy (touch preparation and frozen section)
- Invasive adenocarcinoma with mucinous component.

Note: Reported to [REDACTED]

Intra-Operative Consultation #1 performed by

[REDACTED]

Final Diagnosis performed by

[REDACTED]

(ADDENDUM):

The tumor stains positively for CK7 and CK20, but not for TTF-1 and

[page 3 of 3]
CDX-2. The results support the diagnosis.

Addendum #1 performed by

[REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED]

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 933dd30f-2786-414c-bd1b-47cf13c574e4 (TCGA-97-7552.201ED2F1-C4ED-42AC-81EB-B5A725C36B47.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).